Gene-level copy-number profile of tumor specimen TCGA-K4-A3WV-01A from TCGA case TCGA-K4-A3WV, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 77.9 years (28,444 days).
Specimen TCGA-K4-A3WV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.38e8ed4e-a085-4a5d-9748-70c798dffed6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-K4-A3WV-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (sample pair TCGA-K4-A3WV-01A|TCGA-K4-A3WV-10A); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f79880df-ec9a-4738-9772-94f9b3ac497e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 88; copy number 1: 1,941; copy number 2: 13,226; copy number 3: 25,507; copy number 4: 9,764; copy number 5: 5,444; copy number 6: 1,577; copy number 7: 1,531; copy number 8: 103; copy number 9: 197; copy number 10: 25; copy number 11: 122; copy number 12: 23; copy number 14: 19; copy number 16: 14; copy number 17: 74; copy number 23: 50; copy number 26: 33; copy number 32: 31; copy number 36: 14; copy number 44: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-K4-A3WV-01A-11D-A22Y-01): tumor purity 0.67, ploidy 3.2, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:87,863,703–88,439,337, 7 genes (within-gene range 0–1): AC114971.1, TMEM161B, TMEM161B-AS1, RNA5SP187, RPS3AP22, SNORA70, AC091826.1.
- chr5:90,353,037–94,739,436, 55 genes: AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1, LUCAT1, AC074132.1, AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2, Metazoa_SRP, AC008799.1, AC008799.2, ARRDC3, ARRDC3-AS1, RAB5CP2, AC093298.2, PCBP2P3, AC093298.1, AC114316.1, AC124854.1, AC026780.1, AC026780.2, AC008517.1, LDHBP3, CCT7P2, LINC02058, AC012625.1, AC026408.1, POLD2P1, NR2F1-AS1, NR2F1, AC106818.1, FAM172A, MIR2277, AC106818.2, NPM1P27, POU5F2, AC108102.1, AC099501.1, AC114980.1, AC117528.1, KIAA0825, MTND5P12, MTND6P3, MTCYBP35, AC093311.1, AC025766.1, SLF1.
- chr5:94,788,789–94,980,893, 4 genes: AC008534.1, RPL7P18, AC008534.2, MCTP1-AS1.
- chr6:132,271,982–132,401,475, 2 genes (within-gene range 0–3): EEF1A1P36, MOXD1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–22,128,103, 9 genes (within-gene range 0–2): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr9:132,725,578–132,890,201, 3 genes: AK8, AL445645.1, SPACA9.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,258 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:49,563,388–52,702,615, 25 genes, copy number 7: AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431.
- chr3:139,389,761–139,782,699, 1 gene, copy number 7 (within-gene range 6–7): AC046134.2.
- chr3:139,517,434–179,604,649, 586 genes, copy number 7–11 (broad region; genes not listed).
- chr3:179,794,958–198,222,513, 428 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr4:64,275,257–66,897,371, 30 genes, copy number 7: TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, AC104689.2, LINC02232, AC107058.1, EFL1P2, AC096754.1, LINC02835, EPHA5, AC115223.1, EPHA5-AS1, AC104137.1, RNU2-40P, AC097110.1, AC116049.1, AC096721.1, IFITM3P1, AC110809.1, MIR1269A, RPS23P3, RNU6-699P.
- chr6:1,623,806–2,245,605, 2 genes, copy number 9: GMDS, AL035693.1.
- chr6:10,434,316–10,456,781, 1 gene, copy number 7 (within-gene range 2–7): MIR5689HG.
- chr6:10,459,906–10,478,502, 2 genes, copy number 7: MRPL48P1, LINC02522.
- chr6:10,747,794–10,930,423, 1 gene, copy number 7 (within-gene range 2–7): AL024498.2.
- chr6:10,873,223–11,583,524, 17 genes, copy number 7: GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1, ELOVL2-AS1, SMIM13, ERVFRD-1, AL136139.1, AL139807.1, NEDD9, AL022098.1, AL445430.2, AL445430.1, RNU1-64P, THAP12P5, TMEM170B.
- chr6:12,716,554–15,522,042, 38 genes, copy number 7–10 (within-gene range 2–10): PHACTR1, RNU1-11P, AL008729.1, TBC1D7, AL008729.2, GFOD1, GFOD1-AS1, RPS4XP7, RN7SKP204, SIRT5, AL441883.1, NOL7, RANBP9, Z93020.1, MCUR1, AL023583.1, RNF182, MRPL35P1, AL022396.1, CD83, AL133259.1, RNU7-133P, AL353152.2, AL353152.1, LINC01108, AL080313.2, AL080313.1, AL009177.1, AL109914.1, RNU6-793P, AL138720.1, AL050335.1, RN7SL332P, AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P.
- chr6:20,401,879–25,930,726, 88 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr6:27,357,825–30,744,548, 240 genes, copy number 7 (broad region; genes not listed).
- chr6:30,751,038–30,751,289, 1 gene, copy number 7: RN7SL353P.
- chr8:35,235,475–35,796,550, 1 gene, copy number 44 (within-gene range 1–44): UNC5D.
- chr8:35,525,176–39,838,289, 92 genes, copy number 23–44 (within-gene range 2–44) (broad region; genes not listed).
- chr11:30,323,104–32,458,769, 33 genes, copy number 9–12: ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5, RCN1, AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.
- chr11:34,709,600–35,020,591, 5 genes, copy number 8 (within-gene range 3–8): AC087783.1, AL359999.1, APIP, PDHX, MIR1343.
- chr11:70,270,690–70,436,584, 9 genes, copy number 14: PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,647,562, 4 genes, copy number 14: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2.
- chr11:75,800,877–82,718,299, 100 genes, copy number 7–14 (within-gene range 4–14) (broad region; genes not listed).
- chr12:66,123,917–66,169,985, 1 gene, copy number 7 (within-gene range 4–7): AC078927.1.
- chr12:66,135,846–76,615,567, 179 genes, copy number 7–8 (broad region; genes not listed).
- chr12:106,015,897–106,058,254, 2 genes, copy number 10: ST13P3, AC011595.2.
- chr14:25,267,064–25,432,234, 3 genes, copy number 7: HMGN2P6, OR7K1P, AL079352.1.
- chr14:26,443,090–27,845,286, 10 genes, copy number 9 (within-gene range 3–9): NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1.
- chr14:40,630,006–42,268,586, 10 genes, copy number 8 (within-gene range 3–8): AL390800.1, LINC02315, AL391516.1, AL356596.1, AL121821.3, AL121821.2, AL121821.1, LRFN5, FKBP1BP1, AL445074.1.
- chr18:20,946,906–21,525,417, 9 genes, copy number 16: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1.
- chr18:21,704,957–21,870,953, 1 gene, copy number 7 (within-gene range 6–7): MIB1.
- chr18:21,793,883–25,056,760, 76 genes, copy number 7 (broad region; genes not listed).
- chr18:25,818,234–28,177,946, 39 genes, copy number 7: RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P, AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1.
- chr20:28,563,850–32,439,319, 88 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr22:15,290,718–16,956,808, 72 genes, copy number 17 (broad region; genes not listed).
- chr22:20,495,913–21,551,461, 63 genes, copy number 26–32 (broad region; genes not listed).
- chr22:21,555,138–21,555,457, 1 gene, copy number 32: Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 968. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
